Gene-level copy-number profile of tumor specimen TCGA-24-2267-01A from TCGA case TCGA-24-2267, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 58.3 years (21,293 days).
Specimen TCGA-24-2267-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.c908d760-4c66-4be4-9e87-66ab733a7be6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-2267-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7ee58d4d-36b8-455d-ac7b-e00572a0af30

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,675; copy number 2: 23,204; copy number 3: 18,893; copy number 4: 12,053; copy number 5: 2,810; copy number 6: 1,122; copy number 8: 1; copy number 9: 59.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-2267-01A-01D-0704-01): tumor purity 0.57, ploidy 2.84, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,806 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:18,939,697–37,157,065, 331 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr2:177,623,244–178,108,339, 2 genes, copy number 5 (within-gene range 4–5): PDE11A, PDE11A.
- chr2:177,953,111–204,507,672, 404 genes, copy number 5 (broad region; genes not listed).
- chr3:106,449,775–107,240,671, 1 gene, copy number 5 (within-gene range 4–5): LINC00882.
- chr3:106,848,671–113,965,401, 131 genes, copy number 5 (broad region; genes not listed).
- chr3:166,569,693–180,476,778, 204 genes, copy number 5–9 (broad region; genes not listed).
- chr5:58,198–7,830,081, 152 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr5:19,233,366–31,595,669, 113 genes, copy number 5 (broad region; genes not listed).
- chr5:31,657,218–31,754,656, 7 genes, copy number 5: AC022447.2, AC022447.4, AC022447.5, AC022447.3, AC022447.1, AC022447.7, AC022447.6.
- chr6:57,314,805–57,646,850, 1 gene, copy number 6 (within-gene range 3–6): PRIM2.
- chr6:57,493,855–58,438,364, 14 genes, copy number 6: FO680682.1, AL021368.3, AL021368.5, AL021368.1, AL021368.2, GUSBP4, AL021368.4, POM121L14P, LINC00680, AL445250.1, GAPDHP15, AL390237.1, RBBP4P4, AL603755.1.
- chr7:129,830,732–159,233,377, 677 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr9:1,977,784–20,622,499, 232 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr11:82,729,940–85,811,159, 49 genes, copy number 5 (within-gene range 4–5): FAM181B, LINC02734, RBMXP3, PRCP, EIF2S2P6, DDIAS, AP000893.1, AP000893.2, RAB30, AP001767.1, SNORA70E, RAB30-DT, AP001767.2, AP001767.3, COX5BP4, C1DP5, BCAS2P1, PCF11, AP000873.4, AP000873.2, PCF11-AS1, ANKRD42, CKS1BP4, AP000873.3, AP000873.1, CCDC90B, AP000446.1, CYCSP28, AP000446.2, DLG2, DLG2-AS2, AP002370.1, LDHAL6DP, HNRNPA1P72, AP000852.1, AP001825.1, AP001825.2, AP001825.3, AP000857.2, AP000857.1, HNRNPCP6, AP002803.1, AP003035.1, RNU6-1292P, TMEM126B, TMEM126A, CREBZF, CCDC89, SYTL2.
- chr11:86,703,099–87,721,233, 25 genes, copy number 5: AP003059.1, AP003059.2, PRSS23, MOB4P2, OR7E13P, AP000654.1, OR7E2P, AP001528.1, AP001528.2, FZD4, FZD4-DT, HNRNPCP8, TMEM135, XIAPP2, AP002967.1, AP001102.1, AP000811.1, PSMA2P1, AP003497.1, AP003497.2, AP001784.1, RNU6-1135P, U6, LINC02711, AP000756.1.
- chr19:28,294,093–40,380,439, 463 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,675. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
